Somatic mutation profile of tumor specimen TARGET-30-PASXHE-01A (aliquot TARGET-30-PASXHE-01A-01D) from TARGET case TARGET-30-PASXHE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 3.9 years (1,438 days).
Specimen TARGET-30-PASXHE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4d535a2-ada0-4564-9484-db4f1b2879f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASXHE-10A (Blood Derived Normal), aliquot TARGET-30-PASXHE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdf04fb0-8f35-4490-a7a7-34e6aa917fac

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PROC | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs121918145, CM951006, COSV52167542; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS6 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 18/18 reads (100%) | catalogued as COSV66863404; called by muse, mutect2, varscan2
- CCDC158 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750513601, COSV66356901; called by muse, mutect2, varscan2
- CD163L1 | c.48C>A p.C16* | Nonsense Mutation (SNP) | VAF 48/139 reads (35%) | catalogued as COSV58022432; called by muse, mutect2, varscan2
- CYP27B1 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV56986121; called by muse, mutect2, varscan2
- ERBB3 | c.1019T>C p.F340S | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV57260240; called by muse, mutect2, varscan2
- EVI2B | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 60/135 reads (44%) | catalogued as COSV58364328, COSV58364857; called by muse, mutect2, varscan2
- FNIP2 | c.1333C>T p.H445Y | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52444078; called by muse, mutect2, varscan2
- IQGAP1 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs200740824, COSV51589518; called by muse, mutect2, varscan2
- MAGEB1 | c.956C>A p.S319Y | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.831); catalogued as COSV66776360; called by muse, mutect2, varscan2
- MRPS35 | c.389G>T p.C130F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV50011281, COSV50012131; called by muse, mutect2, varscan2
- MYO3B | c.3149T>A p.V1050D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58713223; called by muse, mutect2, varscan2
- OR2T3 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62083348, COSV62084077; called by muse, mutect2, varscan2
- OR4D1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52125790; called by muse, mutect2, varscan2
- OR51V1 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58316035; called by muse, mutect2, varscan2
- PCDH9 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.932); catalogued as COSV60578517; called by muse, mutect2, varscan2
- PDZD2 | c.6253G>A p.E2085K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs140544837, COSV56877987; called by muse, mutect2, varscan2
- PLXDC1 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59553108; called by muse, mutect2, varscan2
- PMFBP1 | c.2554C>T p.Q852* (on ENST00000537465; = p.Q847* on NM_031293.3) | Nonsense Mutation (SNP) | VAF 109/187 reads (58%) | catalogued as COSV52829933; called by muse, mutect2, varscan2
- PRDM13 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV65030510; called by muse, mutect2, varscan2
- PYROXD2 | c.1216A>C p.I406L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV65331085; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3312G>T p.L1104F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV62786264; called by muse, mutect2, varscan2
- RBM22 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as rs759075356, COSV52272772; called by muse, mutect2, varscan2
- RRP15 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs748000513, COSV65118550; called by muse, mutect2, varscan2
- SLC26A9 | c.819T>G p.N273K | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61604733; called by muse, mutect2, varscan2
- SPAG17 | c.1612-1G>T p.X538_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV60465080; called by muse, mutect2, varscan2
- WDR72 | c.3285G>T p.K1095N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV64752077; called by muse, mutect2, varscan2
- ZC3H10 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.24); catalogued as COSV57769704; called by muse, mutect2, varscan2
- DNAH17 | c.7085C>T p.A2362V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PF4 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2
- SPEF2 | c.2825del p.G942Efs*44 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
- HNF1A | c.1011C>T p.S337= | Silent (SNP) | VAF 174/615 reads (28%) | catalogued as rs549471872, COSV57459928; called by muse, mutect2, varscan2
- MYH8 | c.2805C>A p.I935= | Silent (SNP) | VAF 127/292 reads (43%) | catalogued as COSV67963077, COSV67970465; called by muse, mutect2, varscan2
- NDST3 | c.279A>G p.Q93= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV56626413; called by muse, mutect2, varscan2
- PER3 | c.1008A>G p.E336= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV62707350; called by muse, mutect2, varscan2
- PGLYRP2 | c.729G>T p.L243= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV52996766; called by muse, mutect2, varscan2
- PPP1R16B | c.1659A>T p.I553= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV55382277; called by muse, mutect2, varscan2
